Gene-level copy-number profile of tumor specimen TCGA-13-0911-01A from TCGA case TCGA-13-0911, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 55.5 years (20,276 days).
Specimen TCGA-13-0911-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.b0fb393b-8bbd-4af4-97bd-fb5bc61b1edf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0911-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0d986070-e683-4b23-b002-2954f1f108ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 5; copy number 2: 24,100; copy number 3: 19,842; copy number 4: 10,028; copy number 5: 3,055; copy number 6: 851; copy number 7: 1,613; copy number 8: 175; copy number 9: 121; copy number 12: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0911-01A-01D-0399-01): tumor purity 0.6, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:20,037,560–20,620,561, 4 genes (within-gene range 0–2): AC098862.1, SLIT2, SLIT2-IT1, MIR218-1.
- chr4:180,095,527–180,574,027, 2 genes: AC096747.1, NDUFB5P1.
- chr17:11,874,727–12,143,830, 8 genes: AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,829 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:100,586,649–100,652,267, 4 genes, copy number 7: AC099670.1, LINC01349, AC099670.3, AC099670.2.
- chr1:203,475,806–204,728,106, 43 genes, copy number 6: PRELP, OPTC, ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2.
- chr2:71,453,722–71,686,768, 1 gene, copy number 5 (within-gene range 3–5): DYSF.
- chr2:202,073,255–202,205,188, 1 gene, copy number 5 (within-gene range 3–5): KIAA2012.
- chr2:202,137,570–203,738,912, 51 genes, copy number 5: AC079354.2, AC079354.1, PSMA2P3, DAZAP2P1, SUMO1, RPL39P14, NOP58, SNORD70, SNORD70B, SNORD11B, SNORD11, AC064836.3, RN7SL753P, PIMREGP1, AC064836.1, RN7SL40P, AC064836.2, BMPR2, H3P8, RPL13AP12, MTCO1P17, MTCO2P17, MTATP6P17, MTCO3P17, MTND3P17, MTND4LP17, MTND4P30, MTCO1P54, FAM117B, ICA1L, AC098831.1, KRT8P15, WDR12, CARF, KRT8P52, AC010900.1, NBEAL1, RPL7P14, AC023271.1, AC023271.2, RPL23AP36, RPL12P16, CYP20A1, RN7SL670P, MRPL50P2, ABI2, AC080075.1, RAPH1, AC125238.2, AC125238.1, CD28.
- chr3:8,501,807–10,153,667, 57 genes, copy number 6: LMCD1, AC034187.1, SSUH2, OR7E122P, CAV3, OXTR, RAD18, AC034186.2, AC034186.1, SRGAP3, SRGAP3-AS1, AC037193.1, SRGAP3-AS2, SRGAP3-AS3, SRGAP3-AS4, AC026191.1, PGAM1P4, THUMPD3-AS1, THUMPD3, SETD5, LHFPL4, DUSP5P2, MTMR14, AC022382.2, CPNE9, BRPF1, OGG1, CAMK1, TADA3, ARPC4, ARPC4-TTLL3, TTLL3, AC022382.1, RPUSD3, CIDEC, JAGN1, IL17RE, IL17RC, RNU6-882P, AC018809.3, CRELD1, AC018809.1, PRRT3, PRRT3-AS1, AC018809.2, EMC3, EMC3-AS1, CYCSP10, AC022007.1, CIDECP1, FANCD2, RNU6-670P, CYCSP11, FANCD2OS, BRK1, VHL, AC034193.1.
- chr3:91,356,755–124,726,325, 448 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr3:124,723,788–198,222,513, 1,353 genes, copy number 5–7 (broad region; genes not listed).
- chr5:58,198–50,443,248, 711 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr5:168,661,733–169,301,139, 1 gene, copy number 5 (within-gene range 2–5): SLIT3.
- chr5:168,791,498–181,342,213, 347 genes, copy number 5 (broad region; genes not listed).
- chr6:45,328,157–47,042,350, 23 genes, copy number 7 (within-gene range 4–7): RUNX2, AL096865.1, RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1.
- chr6:55,753,653–56,394,094, 5 genes, copy number 7 (within-gene range 4–7): BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1.
- chr7:43,508,728–45,076,469, 59 genes, copy number 6 (within-gene range 3–6): LUARIS, STK17A, COA1, BLVRA, AC005189.1, MRPS24, URGCP-MRPS24, URGCP, TUBG1P, UBE2D4, POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP, LINC00957, DBNL, MIR6837, PGAM2, AC017116.1, POLM, MIR6838, AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK, YKT6, CAMK2B, AC004453.2, NUDCD3, AC004453.1, RNU6-1097P, AC004938.1, NPC1L1, DDX56, TMED4, AC004938.2, AC011894.1, OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952, PURB, MIR4657, AC004854.2, AC004854.1, AC004847.1, MYO1G, SNHG15, SNORA9, CCM2.
- chr8:33,547,754–34,039,104, 9 genes, copy number 6–12 (within-gene range 4–12): RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1.
- chr8:35,235,475–35,796,550, 1 gene, copy number 6 (within-gene range 4–6): UNC5D.
- chr8:35,525,176–43,674,591, 190 genes, copy number 6 (broad region; genes not listed).
- chr8:51,319,577–51,809,445, 1 gene, copy number 6 (within-gene range 4–6): PXDNL.
- chr8:51,721,670–63,234,911, 178 genes, copy number 6 (broad region; genes not listed).
- chr8:132,120,859–132,675,592, 3 genes, copy number 6 (within-gene range 4–6): KCNQ3, HPYR1, LRRC6.
- chr9:71,683,366–76,651,203, 58 genes, copy number 6 (within-gene range 4–6): CEMIP2, AL671309.1, ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474, ALDH1A1, CYP1D1P, ANXA1, DPP3P2, AL451127.2, AL451127.1, AL512594.1, RNA5SP286, AL513124.1, AL355674.1, RORB-AS1, RORB, AL137018.1, TRPM6, RN7SKP47, RPSAP75, RNU6-445P, AL158825.1, C9orf40, CARNMT1-AS1, CARNMT1, AL158825.2, AL158825.3, NMRK1, OSTF1, Y_RNA, RNU6-1228P, AL158073.1, AL353780.1, OTX2P1, PCSK5, RBM22P5, RFK, RPSAP9, GCNT1, H3P32, PPIAP87.
- chr10:44,712–43,422,100, 716 genes, copy number 5–6 (broad region; genes not listed).
- chr12:52,164,115–59,812,576, 381 genes, copy number 5–7 (broad region; genes not listed).
- chr12:66,023,620–69,855,363, 89 genes, copy number 5 (broad region; genes not listed).
- chr14:76,131,707–77,616,637, 52 genes, copy number 5 (within-gene range 3–5): AC016526.4, GPATCH2L, AC016526.2, AC016526.3, AC016526.1, ESRRB, AC008050.1, CYCSP1, RPSAP3, AC007376.1, AC007376.2, VASH1, AF111169.3, AF111169.1, VASH1-AS1, ANGEL1, AF111169.4, LRRC74A, RPL22P2, RN7SKP17, AF111169.2, AC007686.4, LINC01629, RN7SL356P, AC007686.1, IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289, AC007686.5, CIPC, AC007375.2, TMEM63C, ZDHHC22, AC007375.3, FAM204DP, AC007375.1, NGB, MIR1260A, POMT2, GSTZ1, TMED8, AC007954.1, SAMD15, NOXRED1, VIPAS39, AHSA1, AF111168.1, ISM2, SPTLC2, RN7SL587P.
- chr19:37,497,159–39,111,493, 75 genes, copy number 5 (broad region; genes not listed).
- chr20:30,278,906–64,313,132, 896 genes, copy number 5–7 (broad region; genes not listed).
- chr21:14,485,228–19,345,312, 76 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
